Somatic mutation profile of tumor specimen TCGA-VD-A8K8-01A (aliquot TCGA-VD-A8K8-01A-11D-A39W-08) from TCGA case TCGA-VD-A8K8, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.0 years (20,454 days).
Specimen TCGA-VD-A8K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf309aa4-151d-437a-9c5a-50f6f83879d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8K8-10A (Blood Derived Normal), aliquot TCGA-VD-A8K8-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b2fe6d2-93a9-40ad-a604-1646ff02c782

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKK1 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV58273709; called by muse, mutect2
- GRIN2B | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV101663147; called by muse, mutect2, varscan2
- DROSHA | c.548del p.N183Ifs*43 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- MYOF | c.3637A>T p.M1213L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G4 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (1); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PAX7 | c.1123A>C p.M375L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SGSM1 | c.358A>T p.N120Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TMEM54 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.27); called by muse, mutect2
- TRIM4 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UPK1A | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- IGHE | c.72C>T p.S24= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs1555457222; called by muse, mutect2, varscan2
- SOX14 | c.645C>G p.P215= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1172708903, COSV60163019; called by muse, mutect2, varscan2
